TCGA case TCGA-NC-A5HQ — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Washington University - CHUV. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4b185183-7e94-4aab-b19d-6a2e48b85a5d

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: Switzerland; Age at index: 70 years; Vital status: Dead; Days to death: 448 days (1.2 years).

Diagnoses (1)
1. Squamous cell carcinoma, keratinizing, NOS: ICD-O-3 morphology code: 8071/3; ICD-10 code: C34.2; Tissue or organ of origin: Middle lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 70.6 years (25,781 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Vinorelbine Tartrate; Days to treatment start: 57 days; Days to treatment end: 133 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 158 days; Days to treatment end: 202 days; Treatment dose: 54 Gy; Treatment outcome: Complete Response; Number of fractions: 30; Treatment anatomic sites: Regional Site.

Follow-up (2 entries)
- ECOG performance status: 1; Timepoint: Prior to Adjuvant Therapy.
- Follow-up contact recording only the day: day 448.

Other clinical attributes
- DLCO (% of predicted): 142; FEV1/FVC after bronchodilator (%): 76; FEV1/FVC before bronchodilator (%): 79; FEV1 after bronchodilator (% of reference): 97; FEV1 before bronchodilator (% of reference): 104.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-NC-A5HQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 350 mg.
  Slide TCGA-NC-A5HQ-01A-01-TSA: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-NC-A5HQ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-NC-A5HQ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Performance status timing: Pre-Adjuvant Therapy; Tobacco smoking history indicator: 2; Anatomic organ subdivision: R-Middle; Location lung parenchyma: Central Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Drug treatment 2: Pharmaceutical therapy drug name: Navelbine.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 448 days; disease-specific survival: event status not recorded, 448 days; disease-free interval: no event (censored), 448 days; progression-free interval: no event (censored), 448 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-NC-A5HQ-01A-11D-A26L-01): tumor purity 0.5, ploidy 2.87, whole-genome doublings 1.
